CCDI case PBBYSF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d8a2e6ee-91b3-4506-bd40-20ab1c29bb84

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.3 years (2,683 days).

Biospecimens (3 samples)
- Sample 0DMRAO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMRAW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMRBD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
